Somatic mutation profile of tumor specimen TCGA-B2-5635-01A (aliquot TCGA-B2-5635-01A-01D-1534-10) from TCGA case TCGA-B2-5635, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 74.4 years (27,183 days).
Specimen TCGA-B2-5635-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 171633a7-565f-4e15-ac84-297288883b36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B2-5635-10A (Blood Derived Normal), aliquot TCGA-B2-5635-10A-01D-A270-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec4cd589-5bad-4465-8c4c-2332d0c8b9d5

The open-access MAF lists 62 somatic variants for this specimen: 48 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 12, Frame Shift Del 10, Splice Site 1, Translation Start Site 1, Intron 1, In Frame Del 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.431del p.G144Dfs*15 | Frame Shift Del (DEL) | VAF 199/487 reads (41%) | catalogued as rs869025651, CM058403, CM982008, COSV56544477, COSV56545017; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACOX3 | c.70T>C p.Y24H | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62710847; called by muse, mutect2, varscan2
- ADCY8 | c.1844G>T p.G615V | Missense Mutation (SNP) | VAF 5/137 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.265); catalogued as COSV53896912; called by muse, mutect2
- AKR1B15 | c.809A>G p.K270R | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as COSV71151044, COSV71152438; called by muse, mutect2, varscan2
- AMOTL1 | c.1970A>G p.N657S | Missense Mutation (SNP) | VAF 56/225 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV58565068; called by muse, mutect2, varscan2
- CADPS | c.3724G>C p.D1242H | Missense Mutation (SNP) | VAF 73/146 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51867480; called by muse, mutect2, varscan2
- CD300C | c.548G>C p.R183P | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV58169559; called by muse, mutect2, varscan2
- CHRDL2 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as rs1272782634, COSV55221695; called by muse, mutect2, varscan2
- DAPK1 | c.982A>G p.M328V | Missense Mutation (SNP) | VAF 66/285 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as rs370466694; called by muse, mutect2, varscan2
- DNAH5 | c.12436T>G p.S4146A | Missense Mutation (SNP) | VAF 138/345 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.047); catalogued as COSV54204617, COSV54231804; called by muse, mutect2, varscan2
- DOP1A | c.7054G>C p.V2352L | Missense Mutation (SNP) | VAF 96/401 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV52706914; called by muse, mutect2, varscan2
- EIF2A | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs1304044022, COSV53525429; called by muse, mutect2, varscan2
- EPB41L5 | c.329-1del p.X110_splice | Splice Site (DEL) | VAF 80/412 reads (19%) | catalogued as COSV99758863; called by mutect2, pindel, varscan2
- GCNT2 | c.929T>C p.V310A (on ENST00000379597 / NM_001374747.1; = p.V308A on NM_001491.3) | Missense Mutation (SNP) | VAF 64/310 reads (21%) | SIFT tolerated (0.95); PolyPhen benign (0.028); catalogued as COSV53941111; called by muse, varscan2
- GJA8 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); catalogued as rs781915687, COSV53788224; called by muse, mutect2
- IFT140 | c.272A>T p.Q91L | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.663); catalogued as COSV68485941; called by muse, mutect2, varscan2
- KAT6B | c.5771C>G p.S1924C | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV54742321; called by muse, mutect2, varscan2
- KCNV2 | c.1385A>G p.D462G | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66055548; called by muse, mutect2, varscan2
- KIAA1586 | c.226T>A p.L76M | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.648); catalogued as COSV66056158; called by muse, mutect2, varscan2
- KTI12 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs775602415, COSV65405591; called by muse, mutect2, varscan2
- MBTD1 | c.1090T>A p.F364I | Missense Mutation (SNP) | VAF 124/592 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV64502808; called by muse, mutect2, varscan2
- MCCC1 | c.1151C>G p.A384G | Missense Mutation (SNP) | VAF 168/359 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55606382; called by muse, mutect2, varscan2
- MED13 | c.2015T>C p.V672A | Missense Mutation (SNP) | VAF 166/818 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV67261969; called by muse, mutect2, varscan2
- MUC16 | c.21268C>G p.L7090V | Missense Mutation (SNP) | VAF 119/478 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs763621010, COSV67445588; called by muse, varscan2
- NBAS | c.2502G>T p.M834I | Missense Mutation (SNP) | VAF 71/320 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV55712855, COSV55713784; called by muse, mutect2, varscan2
- NDUFC1 | c.53G>A p.R18K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1291900266, COSV55499317; called by muse, varscan2
- NEBL | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 108/489 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV65799488; called by muse, mutect2, varscan2
- PKP4 | c.2858C>A p.A953E | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV61577877; called by muse, mutect2, varscan2
- PLEKHA2 | c.33_34del p.C11Wfs*9 | Frame Shift Del (DEL) | VAF 52/250 reads (21%) | catalogued as rs940962664; called by pindel, varscan2
- PPP2R2B | c.349C>A p.L117M (on ENST00000394409; = p.L183M on NM_181674.2) | Missense Mutation (SNP) | VAF 72/390 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60753665; called by muse, mutect2, varscan2
- PXDN | c.3205G>A p.A1069T | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53227201, COSV53241593; called by muse, mutect2, varscan2
- RDX | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 111/419 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.904); catalogued as rs150863373; called by muse, mutect2, varscan2
- RTN1 | c.593A>G p.D198G | Missense Mutation (SNP) | VAF 152/480 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774918300, COSV50718848, COSV99955912; called by muse, mutect2, varscan2
- TM6SF1 | c.976A>G p.R326G | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51943091, COSV51944282; called by muse, mutect2, varscan2
- TMEM97 | c.528del p.K176Nfs*188 | Frame Shift Del (DEL) | VAF 40/268 reads (15%) | catalogued as rs781830688; called by mutect2, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 24/200 reads (12%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TSNAXIP1 | c.892A>T p.S298C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as COSV54648201; called by muse, mutect2, varscan2
- TSNAXIP1 | c.893G>A p.S298N | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV54648209; called by muse, mutect2, varscan2
- USF3 | c.914A>G p.H305R | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV57069902; called by muse, varscan2
- UVRAG | c.709del p.S237Vfs*6 | Frame Shift Del (DEL) | VAF 25/146 reads (17%) | catalogued as rs762976381; called by mutect2, varscan2
- ZNF433 | c.1820T>C p.M607T | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.159); catalogued as COSV61398410; called by muse, mutect2, varscan2
- AHNAK2 | c.14814_14831del p.E4938_A4944delinsD | In Frame Del (DEL) | VAF 18/76 reads (24%) | called by mutect2, pindel, varscan2
- APC | c.3909_3915del p.I1304Kfs*2 | Frame Shift Del (DEL) | VAF 22/123 reads (18%) | called by mutect2, pindel, varscan2
- COPA | c.2176_2183del p.R726Hfs*13 | Frame Shift Del (DEL) | VAF 51/241 reads (21%) | called by mutect2, pindel, varscan2
- ESCO2 | c.417del p.K139Nfs*6 | Frame Shift Del (DEL) | VAF 29/170 reads (17%) | called by mutect2, pindel, varscan2
- KDM5C | c.711_751del p.Q237Hfs*12 | Frame Shift Del (DEL) | VAF 64/142 reads (45%) | called by mutect2, pindel
- LRP2 | c.13647del p.N4549Kfs*8 | Frame Shift Del (DEL) | VAF 118/500 reads (24%) | called by mutect2, pindel*, varscan2
- PLA2G4F | c.1692dup p.A565Cfs*6 | Frame Shift Ins (INS) | VAF 16/65 reads (25%) | called by mutect2, pindel, varscan2
- CBFA2T3 | c.1551C>T p.H517= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs1169750562, COSV51923312; called by muse, mutect2, varscan2
- CHD5 | c.567T>G p.G189= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV52407880; called by muse, mutect2, varscan2
- DSG1 | c.3066C>T p.H1022= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as COSV57133270; called by muse, mutect2, varscan2
- HYOU1 | c.2692C>T p.L898= | Silent (SNP) | VAF 41/163 reads (25%) | catalogued as rs1465515962, COSV68215151; called by muse, mutect2, varscan2
- IGF1R | c.66G>A p.A22= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV51270402; called by muse, mutect2, varscan2
- OGG1 | c.180G>C p.A60= | Silent (SNP) | VAF 63/117 reads (54%) | catalogued as rs368830432, COSV57351350; called by muse, mutect2, varscan2
- PDIA6 | c.1281C>T p.L427= | Silent (SNP) | VAF 76/261 reads (29%) | catalogued as COSV55349161, COSV99694377; called by muse, mutect2, varscan2
- RBM47 | c.321C>T p.D107= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV55930240; called by muse, mutect2, varscan2
- SIMC1 | c.1053G>A p.R351= (on ENST00000443967 / NM_001308196.1; = p.R370= on NM_001308195.2) | Silent (SNP) | VAF 24/168 reads (14%) | catalogued as COSV57900197; called by muse, mutect2, varscan2
- SLC5A3 | c.309G>C p.R103= | Silent (SNP) | VAF 136/479 reads (28%) | catalogued as COSV62967904; called by muse, mutect2, varscan2
- SLIT2 | c.1998T>C p.F666= | Silent (SNP) | VAF 62/241 reads (26%) | catalogued as COSV56560594; called by muse, mutect2, varscan2
- TEKT2 | c.1116G>T p.R372= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV99255650; called by muse, mutect2
- AK9 | c.3633+13_3633+16del | Intron (DEL) | VAF 19/210 reads (9%) | catalogued as rs766264675; called by pindel, varscan2*
- DUOXA1 | chr15:45117743 del C | 3'Flank (DEL) | VAF 6/37 reads (16%) | called by mutect2, pindel, varscan2
